Somatic mutation profile of tumor specimen TCGA-IM-A3EB-01A (aliquot TCGA-IM-A3EB-01A-11D-A202-08) from TCGA case TCGA-IM-A3EB, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 32.4 years (11,822 days).
Specimen TCGA-IM-A3EB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cda41ad2-a55c-443c-83d6-823f4a81333e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IM-A3EB-10A (Blood Derived Normal), aliquot TCGA-IM-A3EB-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4422c3da-4914-46ad-b407-7402d7de68f2

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CSRNP2 | c.265G>C p.G89R | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57335009; called by muse, mutect2
- LRPAP1 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs761639938, COSV56346010; called by muse, mutect2
- OR6S1 | c.120T>A p.N40K | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV57838926; called by muse, mutect2, varscan2
- PLA2R1 | c.1568G>T p.G523V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV51784750; called by muse, mutect2, varscan2
- SAMSN1 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs775995897, COSV53470526; called by muse, mutect2, varscan2
- BDP1 | c.923_924del p.T308Rfs*13 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel
- HS3ST5 | c.444T>C p.P148= | Silent (SNP) | VAF 67/205 reads (33%) | catalogued as COSV57148388; called by muse, mutect2, varscan2
- PRSS27 | c.498C>T p.P166= | Silent (SNP) | VAF 81/229 reads (35%) | called by muse, mutect2, varscan2
- TTN | c.34264+5360G>T | Intron (SNP) | VAF 7/25 reads (28%) | catalogued as COSV60261300; called by muse, mutect2, varscan2
